Somatic mutation profile of tumor specimen TARGET-10-PAUAFN-09A (aliquot TARGET-10-PAUAFN-09A-01D) from TARGET case TARGET-10-PAUAFN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,437 days).
Specimen TARGET-10-PAUAFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08886ddf-5dea-4845-94ed-9732c8c26115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUAFN-10A (Blood Derived Normal), aliquot TARGET-10-PAUAFN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/671bb4a7-8543-4558-b805-a49bd1b114ab

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, In Frame Ins 1, Intron 1, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs765856087, COSV56848279; called by muse, mutect2, varscan2
- ARSF | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as rs764500023, COSV63841479; called by muse, mutect2, varscan2
- CCDC168 | c.6715C>T p.R2239C | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs745358492, COSV70556479; called by muse, mutect2, varscan2
- CNNM1 | c.2263C>A p.Q755K | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV63204109; called by muse, mutect2, varscan2
- COL13A1 | c.830C>A p.P277H (on ENST00000398978 / NM_001130103.2; = p.P220H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV62575011; called by muse, mutect2, varscan2
- IL7R | c.726_727insTGCCCGTCA p.L242_L243insCPS | In Frame Ins (INS) | VAF 40/99 reads (40%) | catalogued as COSV57415806; called by mutect2, pindel, varscan2
- MED24 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260703459; called by muse, mutect2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- ZNF740 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs758335267, COSV57239333, COSV99914243; called by muse, mutect2, varscan2
- ZP4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.211); catalogued as rs193920872, COSV63911507, COSV63911552; ClinVar: uncertain significance; called by muse, mutect2
- USP7 | c.1523_1524insGAAG p.H509Kfs*5 | Frame Shift Ins (INS) | VAF 33/69 reads (48%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.616-35_616-34insACTATTGTC | Intron (INS) | VAF 47/126 reads (37%) | called by mutect2, pindel, varscan2
- MEIS3P2 | n.981C>T | RNA (SNP) | VAF 11/91 reads (12%) | catalogued as rs539951955; called by muse, mutect2, varscan2
